CCDI case PBCPKV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/3013d895-68fb-4357-91e2-2a9a8422fca5

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Mixed germ cell tumor: ICD-O-3 morphology code: 9085/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.2 years (2,978 days).

Biospecimens (3 samples)
- Sample 0DWODO: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWODR: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DWODW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
